Somatic mutation profile of tumor specimen 0DV4J0 from CCDI case PBCMEU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pleuropulmonary blastoma; Tissue or organ of origin: Lung, NOS; Age at diagnosis: 2.7 years (990 days).
Specimen 0DV4J0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a0b201ba-b832-4838-a8cc-0616bb7832ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV4IR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efe8f9c1-c00e-4554-8929-80119aed9412

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 4, 3'UTR 3, 5'UTR 1, Splice Region 1, RNA 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 307/782 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM144331, CM146274, CM160048, COSV58615449, COSV58627659; called by muse, mutect2, varscan2
- ARHGAP36 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 262/1535 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV52267579; called by muse, mutect2, varscan2
- FLACC1 | c.1114G>A p.G372R | Missense Mutation (SNP) | VAF 196/1055 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); catalogued as rs1271668446; called by muse, mutect2, varscan2
- MORN1 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 159/802 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs1358522166; called by muse, mutect2, varscan2
- SCN9A | c.2733C>G p.N911K (on ENST00000303354; = p.N900K on NM_002977.3) | Missense Mutation (SNP) | VAF 273/1702 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.329); catalogued as COSV57611794; called by muse, mutect2, varscan2
- SUN2 | c.1399C>G p.R467G | Missense Mutation (SNP) | VAF 93/1006 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs766680217; called by muse, mutect2
- TTN | c.80923C>T p.R26975W (on ENST00000591111; = p.R19551W on NM_003319.4) | Missense Mutation (SNP) | VAF 227/1214 reads (19%) | PolyPhen possibly damaging (0.882); catalogued as rs754025981, COSV59977532; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UNC45B | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 136/800 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs573232689, COSV99268480; called by muse, mutect2, varscan2
- ABCB11 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 269/1369 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- AC004593.2 | c.402G>A p.E134= | Splice Region (SNP) | VAF 214/1080 reads (20%) | called by muse, mutect2, varscan2
- ARAF | c.1173C>A p.Y391* | Nonsense Mutation (SNP) | VAF 81/1285 reads (6%) | called by muse, mutect2
- ATP6V1FNB | c.496T>A p.F166I | Missense Mutation (SNP) | VAF 244/1263 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1G | c.5803A>T p.I1935L | Missense Mutation (SNP) | VAF 144/740 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- COL12A1 | c.6187G>T p.V2063F | Missense Mutation (SNP) | VAF 58/1706 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.83); called by muse, mutect2
- FBRSL1 | c.2238_2242del p.P747Vfs*17 | Frame Shift Del (DEL) | VAF 349/765 reads (46%) | called by mutect2, varscan2
- FCHSD1 | c.1418C>T p.A473V | Missense Mutation (SNP) | VAF 80/1410 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, mutect2
- FOXP1 | c.1061A>T p.Q354L | Missense Mutation (SNP) | VAF 50/1062 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- INPP5E | c.461C>T p.P154L | Missense Mutation (SNP) | VAF 117/562 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- KIAA0586 | c.197T>C p.L66P (on ENST00000619416 / NM_001244190.2; = p.L81P on NM_014749.5) | Missense Mutation (SNP) | VAF 174/956 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- LENG8 | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 40/1052 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2
- MTMR8 | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 68/1690 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.013); called by muse, mutect2
- NSMAF | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 164/1047 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- PCIF1 | c.272C>G p.A91G | Missense Mutation (SNP) | VAF 235/2093 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PLCXD2 | c.189G>C p.W63C | Missense Mutation (SNP) | VAF 62/1086 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEPTIN14 | c.122A>T p.Q41L | Missense Mutation (SNP) | VAF 274/1198 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TMEM39A | c.1328A>T p.E443V | Missense Mutation (SNP) | VAF 100/1513 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2
- FOLH1 | c.1395T>C p.D465= | Silent (SNP) | VAF 222/1103 reads (20%) | catalogued as rs763952088; called by muse, varscan2
- HBS1L | c.1512C>T p.C504= | Silent (SNP) | VAF 220/1481 reads (15%) | catalogued as COSV63202924; called by muse, mutect2, varscan2
- OR10AG1 | c.480C>T p.C160= | Silent (SNP) | VAF 327/1633 reads (20%) | catalogued as rs754960387, COSV56631269; called by muse, mutect2, varscan2
- SLC52A2 | c.1020C>T p.G340= | Silent (SNP) | VAF 266/993 reads (27%) | catalogued as rs1554854405, COSV100095707; called by muse, mutect2, varscan2
- C12orf77 | n.439G>A | RNA (SNP) | VAF 176/848 reads (21%) | called by muse, varscan2
- ESAM | c.*10C>A | 3'UTR (SNP) | VAF 42/732 reads (6%) | called by muse, mutect2
- GPATCH2 | c.-83G>T | 5'UTR (SNP) | VAF 81/177 reads (46%) | catalogued as rs1290023146; called by muse, mutect2, varscan2
- NMRAL1 | c.*7C>G | 3'UTR (SNP) | VAF 35/718 reads (5%) | called by muse, mutect2
- YARS2 | c.*56T>G | 3'UTR (SNP) | VAF 136/532 reads (26%) | called by muse, mutect2, varscan2
